Somatic mutation profile of tumor specimen ALCH-B2UD-TTP1-A (aliquot ALCH-B2UD-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2UD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.0 years (19,343 days).
Specimen ALCH-B2UD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 280dd55f-2e40-4dd9-8358-f7608d418e9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UD-NB1-A (Blood Derived Normal), aliquot ALCH-B2UD-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b0046d9-6cdc-40a3-b0b0-5da9ddac2298

The open-access MAF lists 354 somatic variants for this specimen: 249 protein-altering or splice-affecting, 72 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 214, Silent 72, Nonsense Mutation 22, Intron 17, RNA 9, Splice Region 4, Frame Shift Del 4, Splice Site 3, 5'UTR 3, 3'Flank 2, Translation Start Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 130/441 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALS2CL | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV59670371; called by muse, mutect2
- ANK2 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100001599; called by muse, mutect2, varscan2
- ANKRD34C | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.062); catalogued as rs776218596; called by muse, mutect2, varscan2
- ARC | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV100751773; called by muse, mutect2, varscan2
- ATM | c.4565G>T p.G1522V | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as CM1410495, COSV53730924; called by muse, mutect2, varscan2
- C1orf94 | c.1060C>G p.L354V (on ENST00000488417 / NM_001134734.2; = p.L164V on NM_032884.5) | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs770572991; called by muse, mutect2, varscan2
- CFAP47 | c.4675C>G p.P1559A | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57977383; called by muse, mutect2
- CLVS2 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 32/443 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as COSV51563047; called by muse, mutect2
- CMKLR1 | c.130G>A p.V44M (on ENST00000312143 / NM_001142344.2; = p.V42M on NM_004072.3) | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.387); catalogued as rs761155992; called by muse, mutect2, varscan2
- CNIH1 | c.252T>A p.Y84* | Nonsense Mutation (SNP) | VAF 12/182 reads (7%) | catalogued as rs1359149187; called by muse, mutect2
- COL8A2 | c.1924G>A p.V642M | Missense Mutation (SNP) | VAF 144/578 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs766331675; called by muse, mutect2, varscan2
- CSMD3 | c.7414C>A p.P2472T (on ENST00000297405 / NM_001363185.1; = p.P2368T on NM_052900.3) | Missense Mutation (SNP) | VAF 134/563 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52286373, COSV52342295; called by muse, mutect2, varscan2
- DNAH9 | c.12106-1G>T p.X4036_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV52380637; called by muse, mutect2, varscan2
- DPF3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373920187; called by muse, mutect2
- EXO1 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs202238632; called by muse, mutect2, varscan2
- EXOC2 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57860758; called by muse, mutect2, varscan2
- FAM205A | c.1953C>A p.C651* | Nonsense Mutation (SNP) | VAF 36/377 reads (10%) | catalogued as rs1178401093; called by muse, mutect2, varscan2
- GABRA2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62916321; called by muse, mutect2
- GABRA4 | c.1606G>T p.V536F | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51933777; called by muse, mutect2, varscan2
- GCSAML | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 46/561 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV63578883; called by muse, mutect2
- GLDC | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749512886, COSV100394700; ClinVar: uncertain significance; called by muse, mutect2
- GMPPA | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV58007311; called by muse, mutect2, varscan2
- GOLGA6A | c.569C>G p.S190W | Missense Mutation (SNP) | VAF 79/823 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757384467, COSV99297101; called by muse, mutect2, varscan2
- GREB1L | c.3352C>T p.R1118W | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761699000, COSV99337072; called by muse, mutect2
- GRID2 | c.1554C>A p.D518E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781332931; called by muse, varscan2
- GRM8 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 19/634 reads (3%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.593); catalogued as COSV58848696; called by muse, mutect2
- IGHV3-53 | c.287C>G p.T96R | Missense Mutation (SNP) | VAF 44/457 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as rs1177826860; called by muse, mutect2, varscan2
- IL16 | c.2416C>A p.P806T (on ENST00000302987 / NM_172217.5; = p.P105T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV57260418; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1115T>G p.V372G | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100781502; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1975C>A p.L659M | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV61144087; called by muse, mutect2, varscan2
- KCNH2 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV51162359; called by muse, mutect2, varscan2
- KHDRBS2 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55428911; called by muse, mutect2, varscan2
- LARGE2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201899150, COSV57657053; called by muse, mutect2, varscan2
- LIM2 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702229; called by muse, mutect2, varscan2
- LRIT2 | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs374058743; called by muse, mutect2
- LRP1B | c.10532-1G>T p.X3511_splice | Splice Site (SNP) | VAF 7/201 reads (3%) | catalogued as COSV67199002, COSV67261159; called by muse, mutect2
- MOGAT3 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1056914754; called by muse, mutect2, varscan2
- MYH1 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs750986931; called by muse, mutect2, varscan2
- MYH1 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56848097; called by muse, mutect2
- MYH13 | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | catalogued as COSV52843606; called by muse, mutect2, varscan2
- MYH8 | c.5420C>A p.A1807E | Missense Mutation (SNP) | VAF 64/469 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67960252; called by muse, mutect2, varscan2
- MYO1F | c.636+4C>T | Splice Region (SNP) | VAF 20/158 reads (13%) | catalogued as rs537173637; called by muse, mutect2, varscan2
- OR2M3 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 215/615 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101513404; called by muse, mutect2, varscan2
- PCDHB10 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.85); catalogued as rs1554284055; called by muse, mutect2, varscan2
- PCDHGB2 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.564); catalogued as COSV99530847; called by muse, mutect2
- PCSK5 | c.4424G>T p.C1475F | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774951418; called by muse, mutect2
- PREPL | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150060920, COSV99575952; called by muse, mutect2
- PRKCI | c.1375T>C p.S459P | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.037); catalogued as COSV55521641; called by muse, mutect2
- PZP | c.3221C>A p.T1074K | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); catalogued as rs146198322; called by muse, mutect2, varscan2
- RBM42 | c.337A>G p.M113V | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs912369998; called by muse, mutect2
- REG3A | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59410786, COSV59412087; called by muse, mutect2, varscan2
- SCN10A | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71862589; called by muse, mutect2, varscan2
- SETBP1 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 61/453 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767260608, COSV56341427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC8A2 | c.2324G>T p.C775F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52638760; called by muse, mutect2, varscan2
- SLC9A5 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 35/343 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs1278108133; called by muse, mutect2
- SMO | c.804C>G p.F268L | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV50825887; called by muse, mutect2, varscan2
- SPATA31D1 | c.2042C>A p.S681Y | Missense Mutation (SNP) | VAF 158/717 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV61192485; called by muse, mutect2, varscan2
- SPEG | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1416589728; called by muse, mutect2, varscan2
- SURF6 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs782688340, COSV100921124; called by muse, mutect2, varscan2
- TENM3 | c.4384G>A p.G1462R | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs867464608; called by muse, mutect2, varscan2
- TEX26 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100994137; called by muse, mutect2
- TFAP2A | c.889G>T p.G297* (on ENST00000482890; = p.G289* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 57/400 reads (14%) | catalogued as COSV60237974; called by muse, mutect2, varscan2
- TNN | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 125/297 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs758243448; called by muse, mutect2, varscan2
- TRANK1 | c.1838G>T p.R613L | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV57157505; called by muse, mutect2
- UBE2O | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs769820292; called by muse, mutect2, varscan2
- UBR4 | c.11992C>G p.L3998V | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV64383394; called by muse, mutect2
- UNC5D | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs758920980, COSV54776195, COSV99775410; called by muse, mutect2
- VWA3B | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs867479081; called by muse, mutect2, varscan2
- ZFYVE26 | c.5510G>T p.R1837L | Missense Mutation (SNP) | VAF 82/425 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776920735, COSV61324626, COSV61333877; called by muse, mutect2, varscan2
- ZNF333 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99469647; called by muse, mutect2, varscan2
- ZNF804B | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs990283613; called by muse, mutect2
- ACACB | c.6611G>T p.W2204L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACO1 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS7 | c.3937G>T p.G1313W | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADGRG4 | c.8282C>A p.A2761E | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRV1 | c.7459A>G p.T2487A | Missense Mutation (SNP) | VAF 48/420 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADGRV1 | c.12984G>C p.E4328D | Missense Mutation (SNP) | VAF 26/451 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2
- AMZ1 | c.518T>A p.L173Q | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANK2 | c.6042del p.K2014Nfs*16 | Frame Shift Del (DEL) | VAF 45/360 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD30BL | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- ANO6 | c.1947G>C p.W649C | Missense Mutation (SNP) | VAF 29/586 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- AOX1 | c.1683C>A p.H561Q | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP3B2 | c.2618C>A p.A873D (on ENST00000261722; = p.A867D on NM_004644.5) | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); called by muse, mutect2
- APOB | c.9985A>G p.I3329V | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- APOBEC3G | c.923G>A p.C308Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ARHGAP29 | c.3094A>G p.N1032D | Missense Mutation (SNP) | VAF 9/299 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP35 | c.3042G>T p.M1014I | Missense Mutation (SNP) | VAF 31/438 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- ARHGAP35 | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 31/436 reads (7%) | called by muse, mutect2
- ARPP21 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 15/201 reads (7%) | called by muse, mutect2
- ATP2A3 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AXDND1 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 48/613 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCHE | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BMP7 | c.1009G>T p.V337F | Missense Mutation (SNP) | VAF 137/703 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN2 | c.901_903del p.X301_splice | Splice Site (DEL) | VAF 62/180 reads (34%) | called by mutect2, pindel, varscan2
- CAPSL | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CCDC33 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CDK15 | c.175G>A p.G59R (on ENST00000652192 / NM_001366386.2; = p.G8R on NM_139158.2) | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2
- CDK6 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CELF5 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CEP135 | c.1778A>T p.E593V | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- CHL1 | c.2489G>T p.W830L (on ENST00000397491 / NM_001253387.1; = p.W846L on NM_006614.4) | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CKAP5 | c.2632A>G p.K878E | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- CLK1 | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- CMTR2 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- CNBD1 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- COL4A4 | c.3267G>T p.E1089D | Missense Mutation (SNP) | VAF 19/582 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- COX7B2 | c.152T>A p.V51D | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CRHBP | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRIPT | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRLF1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CSF2RA | c.506T>A p.I169K | Missense Mutation (SNP) | VAF 40/441 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2
- CSTL1 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.871G>T p.E291* (on ENST00000292535 / NM_181552.4; = p.E302* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- CYTIP | c.1003G>T p.G335* | Nonsense Mutation (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- DACH1 | c.1327del p.V443Sfs*12 (on ENST00000619232 / NM_001366712.1; = p.V391Sfs*12 on NM_080759.6) | Frame Shift Del (DEL) | VAF 40/377 reads (11%) | called by mutect2, varscan2
- DCDC1 | c.4125G>T p.K1375N (on ENST00000597505 / NM_001367979.1; = p.K482N on NM_020869.3) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- DISP3 | c.1726T>A p.Y576N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK2 | c.2984T>A p.V995D | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- DPP9 | c.2134G>C p.V712L (on ENST00000598800; = p.V741L on NM_139159.5) | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DYNC1H1 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- EIF4E1B | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- F5 | c.4202C>T p.P1401L | Missense Mutation (SNP) | VAF 44/550 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- FAM170B | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FASTKD3 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 23/542 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.103); called by muse, mutect2
- FCGBP | c.5522G>T p.G1841V | Missense Mutation (SNP) | VAF 25/613 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FHDC1 | c.2187A>T p.R729S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- FHOD3 | c.2204A>T p.D735V (on ENST00000359247 / NM_001281739.3; = p.D752V on NM_025135.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FLG2 | c.6040C>G p.Q2014E | Missense Mutation (SNP) | VAF 241/758 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FXR1 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GAB1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.131); called by muse, mutect2
- GABRA4 | c.1605G>T p.M535I | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GIMAP7 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 64/738 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GLB1L | c.906C>A p.Y302* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- GNAS | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 56/296 reads (19%) | called by muse, mutect2, varscan2
- GRM6 | c.1702C>A p.H568N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HACD3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- HEATR3 | c.1994G>T p.R665L | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2
- HIVEP2 | c.6685G>T p.V2229L | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP2 | c.6684G>T p.M2228I | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- HPS5 | c.2861G>T p.W954L (on ENST00000349215 / NM_181507.2; = p.W840L on NM_007216.4) | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRC | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HYDIN | c.9160G>T p.G3054* | Nonsense Mutation (SNP) | VAF 12/175 reads (7%) | called by muse, varscan2
- IARS2 | c.2747T>C p.I916T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- IHO1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by muse, mutect2
- INO80 | c.2416A>C p.M806L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- JPH2 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- KCNB1 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2
- KCNB2 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KCNH1 | c.1272G>T p.M424I (on ENST00000271751 / NM_172362.3; = p.M397I on NM_002238.4) | Missense Mutation (SNP) | VAF 28/569 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- KCNT2 | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KHNYN | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- KIF4B | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 131/739 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KPRP | c.946A>T p.S316C | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- LILRA5 | c.712+3G>T | Splice Region (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- LMOD1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 142/501 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LOXHD1 | c.5182A>T p.N1728Y (on ENST00000642948; = p.N617Y on NM_001145472.3) | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LRP1B | c.9919del p.A3307Qfs*106 | Frame Shift Del (DEL) | VAF 24/175 reads (14%) | called by mutect2, pindel, varscan2
- LRRC4C | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 32/464 reads (7%) | called by muse, mutect2
- LRRIQ3 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 16/321 reads (5%) | called by muse, mutect2
- MAGI2 | c.2609del p.P870Qfs*70 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- MANEA | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MINDY4 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.412); called by muse, mutect2
- MPDZ | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRPL19 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MS4A13 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MYO15A | c.5738T>C p.L1913P | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, mutect2
- MYO7B | c.3947C>T p.S1316F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDFIP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/235 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- NLRP7 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- NPAS3 | c.2362G>T p.G788W (on ENST00000356141 / NM_001164749.2; = p.G756W on NM_022123.3) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- NUCB2 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUDT17 | c.348C>A p.S116R | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OBP2A | c.510C>A p.H170Q | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10A6 | c.463T>A p.L155I | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR11L1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR4D11 | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 85/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- OR51F2 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ORC5 | c.1042A>G p.S348G | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- OSGEP | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PBX1 | c.797A>T p.K266I | Missense Mutation (SNP) | VAF 12/405 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH15 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 28/517 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2
- PCLO | c.8684G>A p.G2895E | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PCNX1 | c.4543G>T p.V1515F | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PDGFRB | c.2138C>G p.A713G | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PFAS | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF21B | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 13/153 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PLEKHG4B | c.3200G>T p.R1067M (on ENST00000283426; = p.R1423M on NM_052909.5) | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PLPPR4 | c.1785C>A p.N595K | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- PLXNB2 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.193); called by muse, mutect2
- PNCK | c.598G>T p.V200F (on ENST00000340888 / NM_001366975.1; = p.V283F on NM_001039582.3) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PNLDC1 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- PNLIPRP3 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PRUNE2 | c.3512A>T p.Q1171L | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PWWP3B | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- RAPSN | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- RNF165 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RNF214 | c.1420A>T p.M474L | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SACM1L | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2
- SEC23B | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SELP | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SEMA4B | c.1271A>G p.K424R | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SERPINB7 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SLC12A4 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- SLC13A5 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC43A2 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- SLC5A4 | c.1090T>A p.Y364N | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC6A18 | c.906C>A p.Y302* | Nonsense Mutation (SNP) | VAF 52/297 reads (18%) | called by muse, mutect2, varscan2
- SLC6A5 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.1064T>G p.V355G | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SOX17 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SPATA31A6 | c.2103G>T p.L701F | Missense Mutation (SNP) | VAF 24/1067 reads (2%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SPHKAP | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SPRED1 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SRBD1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SSTR2 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STARD13 | c.2394C>A p.N798K (on ENST00000336934 / NM_001243476.3; = p.N680K on NM_052851.3) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- STX18 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.035); called by muse, mutect2
- STXBP5L | c.2839C>A p.H947N | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.129); called by muse, mutect2
- TANC2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TBC1D10C | c.648+4A>G | Splice Region (SNP) | VAF 25/299 reads (8%) | called by muse, mutect2
- TBX4 | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TENM3 | c.3982C>A p.P1328T | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGIF2LY | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 89/661 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMD4 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 74/816 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- TMEM200A | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TNFRSF8 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRPM6 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TTBK1 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TTC21B | c.2856A>T p.E952D | Missense Mutation (SNP) | VAF 139/628 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTC5 | c.195G>T p.Q65H | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2
- TTN | c.25351G>T p.V8451L (on ENST00000591111; = p.V7524L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/254 reads (7%) | PolyPhen benign (0); called by muse, mutect2
- UFL1 | c.1515A>T p.L505F | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UPK1B | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- USH2A | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2
- USP31 | c.1208G>C p.R403T | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); called by muse, mutect2
- VSIG10L2 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2
- WIPF1 | c.1476A>T p.E492D | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- WIPI1 | c.904A>T p.R302W | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED9 | c.3029A>G p.K1010R | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2
- ZFP57 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF189 | c.1552G>T p.G518* | Nonsense Mutation (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- ZNF382 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF514 | c.-8G>T | Splice Region (SNP) | VAF 67/308 reads (22%) | called by muse, mutect2, varscan2
- ZNF556 | c.927C>A p.H309Q | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF560 | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ZNF728 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- ZNF729 | c.1250C>A p.S417* | Nonsense Mutation (SNP) | VAF 71/495 reads (14%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS10 | c.681C>A p.G227= | Silent (SNP) | VAF 65/327 reads (20%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1959G>A p.R653= | Silent (SNP) | VAF 10/287 reads (3%) | catalogued as COSV52825623; called by muse, mutect2
- ADGRB3 | c.3321C>A p.P1107= | Silent (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- AHNAK | c.17367C>T p.F5789= | Silent (SNP) | VAF 47/183 reads (26%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1515G>T p.V505= | Silent (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- ARAP3 | c.2832G>A p.G944= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- ARHGEF16 | c.1575G>A p.T525= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as rs749868678, COSV65681586; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2145C>T p.H715= | Silent (SNP) | VAF 46/537 reads (9%) | catalogued as rs1274418019; called by muse, mutect2
- CAPSL | c.216T>A p.A72= | Silent (SNP) | VAF 14/377 reads (4%) | called by muse, mutect2
- CCSER1 | c.381A>T p.I127= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- CDCA3 | c.324A>G p.P108= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CIP2A | c.1806G>A p.E602= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV55417117; called by muse, mutect2, varscan2
- CITED4 | c.432G>T p.S144= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs755035638, COSV65468367; called by muse, mutect2, varscan2
- CKAP5 | c.1887A>T p.L629= | Silent (SNP) | VAF 35/429 reads (8%) | called by muse, mutect2
- CNTNAP2 | c.1464T>A p.L488= | Silent (SNP) | VAF 64/491 reads (13%) | called by muse, mutect2, varscan2
- CT55 | c.90A>T p.P30= | Silent (SNP) | VAF 55/138 reads (40%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.1116C>A p.L372= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100151008, COSV60478672; called by muse, mutect2
- DNA2 | c.1008C>G p.L336= | Silent (SNP) | VAF 21/478 reads (4%) | called by muse, mutect2
- DNAH2 | c.8121G>T p.T2707= | Silent (SNP) | VAF 50/344 reads (15%) | catalogued as COSV66718857; called by muse, mutect2, varscan2
- DYNC2H1 | c.7893C>T p.H2631= | Silent (SNP) | VAF 28/235 reads (12%) | catalogued as rs373294424; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETV3 | c.1149A>G p.E383= | Silent (SNP) | VAF 98/342 reads (29%) | called by muse, mutect2, varscan2
- EVX1 | c.789G>T p.A263= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- FCGBP | c.2529G>A p.A843= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs754196325; called by muse, mutect2, varscan2
- FOXG1 | c.1395G>T p.T465= | Silent (SNP) | VAF 100/500 reads (20%) | catalogued as COSV57394845; called by muse, mutect2, varscan2
- FUT7 | c.165C>A p.P55= | Silent (SNP) | VAF 9/226 reads (4%) | called by muse, mutect2
- GABRA3 | c.1071C>T p.A357= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as rs1356932229; called by muse, mutect2, varscan2
- GCNT1 | c.417G>T p.L139= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- GDF1 | c.441G>A p.L147= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs1356509629; called by muse, mutect2, varscan2
- GDPD2 | c.204C>T p.F68= | Silent (SNP) | VAF 7/144 reads (5%) | catalogued as rs1238215059; called by muse, mutect2
- HHIPL1 | c.954G>T p.L318= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- HSPG2 | c.7485A>T p.P2495= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV65971136; called by muse, mutect2, varscan2
- IGF1 | c.258G>T p.A86= | Silent (SNP) | VAF 68/421 reads (16%) | catalogued as COSV61032068; called by muse, mutect2, varscan2
- KCNK2 | c.657C>A p.T219= (on ENST00000444842 / NM_001017425.3; = p.T204= on NM_014217.4) | Silent (SNP) | VAF 69/195 reads (35%) | catalogued as rs1423886430; called by muse, mutect2, varscan2
- LMX1A | c.327G>T p.R109= | Silent (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- LOXHD1 | c.1878C>A p.G626= | Silent (SNP) | VAF 28/267 reads (10%) | called by muse, mutect2, varscan2
- LRP1B | c.6933C>A p.V2311= | Silent (SNP) | VAF 46/267 reads (17%) | catalogued as COSV101253764; called by muse, mutect2, varscan2
- MADD | c.3060C>T p.L1020= | Silent (SNP) | VAF 22/302 reads (7%) | catalogued as COSV60624025; called by muse, mutect2
- MAPK4 | c.114G>T p.V38= | Silent (SNP) | VAF 47/343 reads (14%) | called by muse, mutect2, varscan2
- MCOLN2 | c.1242G>T p.L414= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- MSI2 | c.207C>T p.F69= | Silent (SNP) | VAF 56/588 reads (10%) | catalogued as rs1180857593; called by muse, mutect2
- NIN | c.3915C>T p.L1305= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs758724780; called by muse, mutect2, varscan2
- NLK | c.192A>G p.V64= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- NPHS1 | c.171C>A p.T57= | Silent (SNP) | VAF 29/327 reads (9%) | called by muse, mutect2
- NPY1R | c.921C>A p.L307= | Silent (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- NRK | c.555G>T p.L185= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as COSV54596318; called by muse, mutect2, varscan2
- OCSTAMP | c.547C>A p.R183= | Silent (SNP) | VAF 51/197 reads (26%) | called by muse, mutect2, varscan2
- OR4K14 | c.678C>A p.I226= | Silent (SNP) | VAF 58/279 reads (21%) | catalogued as COSV59292379, COSV59293819; called by muse, mutect2, varscan2
- OR6B1 | c.402C>A p.T134= | Silent (SNP) | VAF 9/168 reads (5%) | catalogued as rs976289610; called by muse, mutect2
- PCDH15 | c.4824C>A p.S1608= | Silent (SNP) | VAF 19/689 reads (3%) | called by muse, mutect2
- PCDHA2 | c.1437G>T p.A479= | Silent (SNP) | VAF 28/594 reads (5%) | catalogued as COSV100973853, COSV65366604; called by muse, mutect2
- PCDHA5 | c.1680C>T p.N560= | Silent (SNP) | VAF 32/480 reads (7%) | catalogued as rs781952897, COSV100972487, COSV65349512; called by muse, mutect2
- PCDHA5 | c.2197C>A p.R733= | Silent (SNP) | VAF 37/323 reads (11%) | catalogued as rs140039635; called by muse, mutect2, varscan2
- PLCG1 | c.6G>A p.A2= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- PLCL1 | c.373C>A p.R125= | Silent (SNP) | VAF 14/242 reads (6%) | catalogued as COSV70838744; called by muse, mutect2
- PSD3 | c.2721A>G p.A907= (on ENST00000440756; = p.A906= on NM_015310.4) | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as rs992291557; called by muse, mutect2
- PSG6 | c.519G>A p.P173= | Silent (SNP) | VAF 76/382 reads (20%) | catalogued as rs1065506; called by muse, mutect2, varscan2
- PZP | c.3927C>A p.I1309= | Silent (SNP) | VAF 44/369 reads (12%) | called by muse, mutect2, varscan2
- RABGAP1 | c.1860T>C p.F620= | Silent (SNP) | VAF 31/333 reads (9%) | called by muse, mutect2
- RANBP6 | c.393G>A p.E131= | Silent (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- SCUBE1 | c.1416C>T p.L472= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs1007862970; called by muse, mutect2, varscan2
- SGCD | c.117G>C p.L39= (on ENST00000435422 / NM_001128209.2; = p.L40= on NM_000337.5) | Silent (SNP) | VAF 9/262 reads (3%) | called by muse, mutect2
- SLC13A5 | c.675C>A p.T225= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV53425172; called by muse, mutect2, varscan2
- SLC52A2 | c.1095G>T p.L365= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57352762; called by mutect2, varscan2
- SLCO5A1 | c.972T>A p.I324= | Silent (SNP) | VAF 46/416 reads (11%) | called by muse, varscan2
- TEX55 | c.792G>A p.G264= | Silent (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- TRPC7 | c.852A>T p.T284= | Silent (SNP) | VAF 48/405 reads (12%) | called by muse, mutect2, varscan2
- UQCRC2 | c.426A>T p.T142= | Silent (SNP) | VAF 26/441 reads (6%) | called by muse, mutect2
- USP11 | c.2211C>T p.V737= (on ENST00000218348; = p.V694= on NM_001371072.1) | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- XIRP2 | c.3855T>A p.T1285= (on ENST00000628543; = p.T1460= on NM_152381.6) | Silent (SNP) | VAF 32/256 reads (13%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3393C>T p.S1131= | Silent (SNP) | VAF 41/339 reads (12%) | called by muse, mutect2, varscan2
- ZNF468 | c.135C>A p.V45= | Silent (SNP) | VAF 33/306 reads (11%) | called by muse, mutect2, varscan2
- ZNF536 | c.684G>T p.P228= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV62833902; called by muse, mutect2, varscan2
- AC244258.1 | n.532C>A | RNA (SNP) | VAF 27/214 reads (13%) | catalogued as rs1403798102; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701197 G>T | 3'Flank (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- CCND3 | c.574+24del | Intron (DEL) | VAF 24/227 reads (11%) | called by mutect2, pindel, varscan2
- CHN1 | c.550-763G>T | Intron (SNP) | VAF 44/379 reads (12%) | called by muse, mutect2, varscan2
- CLN3 | c.388+27G>T | Intron (SNP) | VAF 50/285 reads (18%) | called by muse, mutect2, varscan2
- CLU | c.-29-1092C>T | Intron (SNP) | VAF 24/400 reads (6%) | called by muse, mutect2
- CRACD | c.285+1281C>A | Intron (SNP) | VAF 58/323 reads (18%) | called by muse, mutect2, varscan2
- FAM27E5 | n.249C>A | RNA (SNP) | VAF 26/154 reads (17%) | called by mutect2, varscan2
- FAM27E5 | n.250A>T | RNA (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- FAM27E5 | n.410C>T | RNA (SNP) | VAF 25/344 reads (7%) | called by muse, mutect2
- GRB10 | c.846+54C>G | Intron (SNP) | VAF 14/490 reads (3%) | called by muse, mutect2
- GUSBP10 | n.600G>T | RNA (SNP) | VAF 66/368 reads (18%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.16C>A | RNA (SNP) | VAF 31/247 reads (13%) | catalogued as rs773070134; called by muse, mutect2, varscan2
- LRSAM1 | c.252+39G>C | Intron (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- MIR539 | n.58G>T | RNA (SNP) | VAF 46/257 reads (18%) | called by muse, mutect2, varscan2
- MIR544A | n.1A>G | RNA (SNP) | VAF 76/442 reads (17%) | called by muse, varscan2
- NHSL2 | chrX:72143395 A>C | 3'Flank (SNP) | VAF 77/186 reads (41%) | called by muse, mutect2, varscan2
- NT5DC2 | c.121+968dup | Intron (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- PREX1 | c.*25C>A | 3'UTR (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- RFX5 | c.473+26del | Intron (DEL) | VAF 122/519 reads (24%) | called by mutect2, pindel, varscan2
- RNPS1 | c.-11A>T | 5'UTR (SNP) | VAF 43/251 reads (17%) | called by muse, mutect2, varscan2
- RPL18 | c.198+245C>T | Intron (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- SERPINA10 | c.-51+498C>T | Intron (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- SERPINA13P | n.863G>T | RNA (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2
- SLIT2 | c.3088+13G>T | Intron (SNP) | VAF 21/357 reads (6%) | called by muse, mutect2
- SMIM2 | c.*48A>G | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- SPATA7 | c.19+48G>T | Intron (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- SRPK1 | c.74+117G>C | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- TMEM68 | c.687+12A>T | Intron (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100588026; called by muse, mutect2
- UBE2K | c.-10G>T | 5'UTR (SNP) | VAF 33/215 reads (15%) | called by muse, mutect2, varscan2
- UGT3A1 | c.94+39C>A | Intron (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- ZEB2 | c.73+5164C>A | Intron (SNP) | VAF 8/234 reads (3%) | called by muse, mutect2
- ZNF606 | c.-29G>T | 5'UTR (SNP) | VAF 32/421 reads (8%) | catalogued as rs1398822568; called by muse, mutect2
